Somatic mutation profile of tumor specimen TCGA-FW-A3TV-06A (aliquot TCGA-FW-A3TV-06A-11D-A23B-08) from TCGA case TCGA-FW-A3TV, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 57.4 years (20,972 days).
Specimen TCGA-FW-A3TV-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc2881cc-7617-4593-b8df-bb92862091d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FW-A3TV-10A (Blood Derived Normal), aliquot TCGA-FW-A3TV-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94026607-b0ae-44f9-ba2b-f966b5bbedb3

The open-access MAF lists 404 somatic variants for this specimen: 258 protein-altering or splice-affecting, 133 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 236, Silent 133, Nonsense Mutation 14, Intron 5, Splice Region 4, RNA 4, 3'UTR 3, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL2 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 49/108 reads (45%) | hotspot (GDC flag); catalogued as COSV55455231; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- RYR2 | c.3271G>A p.E1091K | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs730880191, COSV63662175, COSV63707708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519858, COSV104400712, COSV58820918, COSV58830935; ClinVar: likely pathogenic; called by mutect2, varscan2
- A4GNT | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as rs553089322, COSV52628584; called by muse, mutect2, varscan2
- ABCC10 | c.1922C>T p.S641F (on ENST00000372530 / NM_001198934.2; = p.S613F on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1310346472, COSV55085474; called by muse, mutect2, varscan2
- ABCC9 | c.2646C>T p.I882= | Splice Region (SNP) | VAF 12/34 reads (35%) | catalogued as COSV53965016, COSV53985347; called by muse, mutect2, varscan2
- ABHD2 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748725026, COSV61773037; called by muse, mutect2, varscan2
- ABLIM2 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56401412; called by muse, mutect2, varscan2
- ACSS1 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV60218445; called by muse, mutect2, varscan2
- ADAMTS9 | c.5043G>A p.W1681* | Nonsense Mutation (SNP) | VAF 37/102 reads (36%) | catalogued as COSV55775876; called by muse, mutect2, varscan2
- AHNAK2 | c.11012A>T p.D3671V | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV60910347; called by muse, mutect2, varscan2
- ANGPTL1 | c.1291A>T p.N431Y | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52365691; called by muse, mutect2, varscan2
- ANK1 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs1250457932, COSV55876208; called by muse, mutect2, varscan2
- APOB | c.7591G>A p.E2531K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs149358359; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARAP3 | c.3270C>T p.I1090= | Splice Region (SNP) | VAF 17/44 reads (39%) | catalogued as rs146842496; called by muse, mutect2, varscan2
- ARF6 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs780782180, COSV53597338; called by muse, mutect2, varscan2
- ARGFX | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.801); catalogued as COSV57681789, COSV57683101; called by muse, mutect2, varscan2
- ARMC4 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53463589; called by muse, mutect2
- ATP13A4 | c.2999C>T p.S1000F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs762150051, COSV61317460; called by muse, mutect2, varscan2
- ATP8B4 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV52711156; called by muse, mutect2, varscan2
- BABAM2 | c.1037dup p.N346Kfs*12 | Frame Shift Ins (INS) | VAF 33/80 reads (41%) | catalogued as rs1477177585; called by mutect2, varscan2
- BIRC6 | c.548T>A p.I183N | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV70196769; called by muse, mutect2
- BPIFA2 | c.371A>C p.N124T | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.048); catalogued as COSV53610514; called by muse, mutect2, varscan2
- BTN3A3 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55071156; called by muse, mutect2, varscan2
- BTNL8 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.852); catalogued as COSV51457518; called by muse, varscan2
- C2orf78 | c.2258G>A p.R753Q | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs777924523, COSV68516760; called by muse, mutect2, varscan2
- C8A | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV63483374; called by muse, mutect2, varscan2
- C9 | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs746437123, COSV54675112; called by muse, mutect2, varscan2
- CATSPER1 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV56409376; called by muse, mutect2, varscan2
- CCDC93 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1355392634, COSV60119489; called by muse, mutect2, varscan2
- CD180 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV56517225; called by muse, mutect2, varscan2
- CD1E | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV63770358; called by muse, mutect2, varscan2
- CD86 | c.592G>A p.D198N (on ENST00000330540 / NM_175862.5; = p.D192N on NM_006889.4) | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1374659487, COSV52605043; called by muse, mutect2, varscan2
- CDR1 | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV65163949; called by muse, mutect2, varscan2
- CELSR1 | c.4015C>T p.R1339W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99419784; called by muse, mutect2, varscan2
- CFAP206 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1405987812, COSV65806689; called by muse, mutect2, varscan2
- CFAP74 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.844); catalogued as COSV54565495; called by muse, mutect2, varscan2
- CLASP1 | c.769T>A p.S257T | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); catalogued as COSV55316984; called by muse, mutect2, varscan2
- COL19A1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.689); catalogued as rs1319595281, COSV59567989; called by muse, mutect2, varscan2
- COL4A3 | c.3152G>A p.G1051E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59257652; called by muse, mutect2, varscan2
- CPEB4 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as rs1393468919, COSV54170301; called by muse, mutect2, varscan2
- CPLX2 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV63999831; called by muse, mutect2, varscan2
- CRACD | c.1245G>A p.W415* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV51717180, COSV99949913; called by muse, mutect2
- CRNN | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 77/284 reads (27%) | catalogued as COSV55120622; called by muse, mutect2, varscan2
- CRY2 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69888262; called by muse, mutect2, varscan2
- CSMD1 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs868276056, COSV68178746; called by muse, mutect2, varscan2
- CYP26A1 | c.1480C>T p.H494Y | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV56417457; called by muse, mutect2, varscan2
- DAB2IP | c.2075C>T p.S692F (on ENST00000408936; = p.S664F on NM_032552.3) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV99406625; called by muse, mutect2, varscan2
- DAB2IP | c.2076C>T p.S692= (on ENST00000408936; = p.S664= on NM_032552.3) | Splice Region (SNP) | VAF 13/30 reads (43%) | catalogued as rs555959752, COSV52263020; called by muse, mutect2, varscan2
- DAPK3 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56662419; called by muse, mutect2, varscan2
- DCAF11 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV58108520; called by muse, mutect2, varscan2
- DGKK | c.3045G>A p.W1015* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV101053285; called by muse, mutect2, varscan2
- DHODH | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54661418; called by muse, mutect2, varscan2
- DLG4 | c.1505T>G p.L502* (on ENST00000399506 / NM_001321075.3; = p.L545* on NM_001365.4) | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV57237132; called by muse, mutect2, varscan2
- DMRTC2 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54186045; called by muse, mutect2, varscan2
- DNAH9 | c.4261C>T p.R1421W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs763130440, COSV52339615; called by muse, mutect2, varscan2
- DOCK11 | c.3019C>T p.P1007S | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV52235223; called by muse, mutect2, varscan2
- E2F4 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58873618; called by muse, mutect2, varscan2
- EDEM1 | c.1158A>T p.K386N | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV56581255; called by muse, mutect2, varscan2
- EEA1 | c.3331G>A p.E1111K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.257); catalogued as COSV59283546; called by muse, mutect2, varscan2
- EML3 | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV53881713; called by muse, mutect2, varscan2
- EML5 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs747945293, COSV61342955; called by muse, mutect2, varscan2
- ENPEP | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs1489093019, COSV54447993; called by muse, mutect2, varscan2
- ENTR1 | c.1004C>T p.T335I (on ENST00000357365 / NM_001039707.2; = p.T312I on NM_006643.4) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53740866; called by muse, mutect2
- ERCC3 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 205/731 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53426062; called by muse, mutect2, varscan2
- ERICH1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as COSV50637420; called by muse, mutect2, varscan2
- ERICH6 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); catalogued as COSV55799333; called by muse, varscan2
- F2RL2 | c.358T>A p.F120I | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV56970094; called by muse, mutect2, varscan2
- F9 | c.1261G>A p.G421R | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV54379247; called by muse, mutect2, varscan2
- FAAH2 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1254403222, COSV66506076, COSV66506223; called by muse, mutect2
- FAM107A | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1273005091, COSV62980407; called by muse, mutect2, varscan2
- FAM122B | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53230719; called by muse, mutect2, varscan2
- FAM184A | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58852471; called by muse, mutect2, varscan2
- FAM47A | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); catalogued as COSV60494955, COSV60498067; called by muse, mutect2, varscan2
- FAM81B | c.988G>A p.G330S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.013); catalogued as COSV51981313; called by muse, mutect2, varscan2
- FAM83B | c.2993G>A p.G998E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as rs267601082, COSV60919114; called by muse, mutect2, varscan2
- FAM83C | c.1807G>A p.A603T | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV65582343; called by muse, mutect2, varscan2
- FBXW12 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV56483210, COSV56483438; called by muse, mutect2, varscan2
- FCER1A | c.113G>A p.W38* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV63666731; called by muse, mutect2, varscan2
- FCRLA | c.905C>T p.S302L (on ENST00000367959; = p.S279L on NM_032738.4) | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); catalogued as COSV52684729; called by muse, mutect2, varscan2
- FGD1 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64308259; called by muse, mutect2, varscan2
- FGFR1 | c.1448C>T p.P483L (on ENST00000447712 / NM_023110.3; = p.P481L on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58330195; called by muse, mutect2, varscan2
- FLNC | c.5221G>A p.E1741K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs200792813; ClinVar: uncertain significance; called by muse, mutect2
- FLVCR2 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1464297176, COSV99471680; called by muse, mutect2, varscan2
- FNDC8 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV50100765; called by muse, mutect2, varscan2
- FYB1 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as COSV60940176, COSV60947622; called by muse, mutect2, varscan2
- GBA3 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV72437857; called by muse, mutect2, varscan2
- GLIS3 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.982); catalogued as COSV60925605; called by muse, mutect2
- GLYATL2 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.198); catalogued as COSV54849326; called by muse, mutect2, varscan2
- GOLGA5 | c.878C>A p.A293D | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV50832262; called by muse, mutect2, varscan2
- GPATCH1 | c.2306C>T p.S769F | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV50112066; called by muse, mutect2, varscan2
- GPRASP1 | c.2175G>A p.W725* | Nonsense Mutation (SNP) | VAF 57/171 reads (33%) | catalogued as COSV64355024; called by muse, mutect2, varscan2
- GRIA4 | c.283T>A p.F95I | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.345); catalogued as COSV56886093; called by muse, mutect2, varscan2
- GYS2 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53921313; called by muse, mutect2, varscan2
- HCFC1 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV60070202; called by muse, mutect2, varscan2
- HEATR4 | c.2123G>A p.G708E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100620661; called by muse, mutect2, varscan2
- HEPHL1 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs960176530, COSV59890121; called by muse, mutect2
- HSPA14 | c.824T>G p.L275W | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65684069; called by muse, mutect2, varscan2
- HUNK | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs141493785; called by muse, mutect2, varscan2
- IFNA1 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV99440043; called by muse, mutect2, varscan2
- IHO1 | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.965); catalogued as rs1022513567, COSV99606727; called by muse, mutect2, varscan2
- IL18R1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs758653418, COSV52123089; called by muse, mutect2, varscan2
- INHBE | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV56987594; called by muse, mutect2, varscan2
- INMT | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs201521957, COSV50000467, COSV50002990; called by muse, mutect2, varscan2
- ISM2 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs138409143; called by muse, mutect2, varscan2
- ITGA9 | c.468C>G p.I156M | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.827); catalogued as COSV53238020; called by muse, mutect2, varscan2
- ITPKB | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV99685372; called by muse, mutect2, varscan2
- ITPR3 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65406795; called by muse, mutect2, varscan2
- KANK2 | c.2279C>T p.A760V (on ENST00000586659 / NM_001379562.1; = p.A768V on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV100763491; called by muse, mutect2, varscan2
- KCNJ1 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761781140, CM095060, COSV60661488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK18 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs552800446, COSV57971233; called by muse, mutect2, varscan2
- KCNT2 | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54065998; called by muse, mutect2, varscan2
- KCNU1 | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV67754002; called by muse, mutect2, varscan2
- KEL | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs762799244, CD151479, COSV62333883; called by muse, mutect2, varscan2
- KIAA0586 | c.3554C>T p.P1185L (on ENST00000619416 / NM_001244190.2; = p.P1124L on NM_014749.5) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs539304161, COSV54172653; called by muse, mutect2, varscan2
- KIF1C | c.2744C>T p.S915L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as rs549971892, COSV100297071, COSV57903393; called by muse, mutect2, varscan2
- KLHL38 | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1426806469, COSV100384508, COSV58086448; called by muse, mutect2, varscan2
- LMOD2 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867202371, COSV71755577; called by muse, mutect2, varscan2
- LPAR3 | c.117T>G p.F39L | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV65452978; called by muse, mutect2, varscan2
- LRP1B | c.13001C>T p.S4334L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV67191718; called by muse, mutect2, varscan2
- LRRC43 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as COSV60288519; called by muse, mutect2, varscan2
- MAGEA10 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 85/264 reads (32%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.495); catalogued as COSV54883295; called by muse, mutect2, varscan2
- MAGEC3 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs758989764, COSV53577293; called by muse, mutect2, varscan2
- MAP2 | c.2498C>T p.S833L | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52284405, COSV52305339; called by muse, mutect2, varscan2
- MARCO | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV100503603, COSV59052677; called by muse, mutect2, varscan2
- MAST4 | c.2506G>A p.E836K (on ENST00000403625 / NM_001164664.2; = p.E647K on NM_015183.3) | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55118548; called by muse, mutect2, varscan2
- MBD5 | c.4019T>G p.F1340C | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1406467148, COSV68696133; called by muse, mutect2, varscan2
- MBNL2 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV59118744; called by muse, mutect2, varscan2
- MDN1 | c.5254G>A p.E1752K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101021307, COSV101021969; called by muse, mutect2, varscan2
- MECOM | c.772C>T p.P258S (on ENST00000468789 / NM_001105078.4; = p.P446S on NM_004991.4) | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as rs267599686, COSV52959125; called by muse, mutect2, varscan2
- MECP2 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs782171742, COSV57652398; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEPE | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs150973660, COSV63072170; called by muse, mutect2, varscan2
- MSH4 | c.2220G>A p.M740I | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV54198431; called by muse, mutect2, varscan2
- MUC16 | c.15796G>A p.E5266K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as rs772876704, COSV67452529; called by muse, mutect2, varscan2
- MUC5B | c.13931G>A p.G4644E | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV71590543; called by muse, mutect2, varscan2
- MUCL3 | c.1265C>T p.P422L (on ENST00000304311; = p.P1298L on NM_080870.4) | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.636); catalogued as COSV58516489; called by muse, mutect2, varscan2
- MXRA5 | c.7148C>T p.P2383L | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54227988; called by muse, mutect2, varscan2
- MYBBP1A | c.1662T>G p.N554K | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV54594940, COSV99626255; called by muse, mutect2, varscan2
- MYO7B | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as rs563118213, COSV67345444; called by muse, mutect2, varscan2
- MYOZ3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.78); catalogued as rs758215148, COSV51739201, COSV51739723; called by muse, mutect2, varscan2
- NAV3 | c.4784A>T p.N1595I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57067384; called by muse, mutect2, varscan2
- NBEA | c.3074G>A p.R1025Q | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.267); catalogued as rs764646547, COSV59767353; called by muse, mutect2, varscan2
- NCF4 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as rs867342643, COSV50620549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEB | c.11698T>A p.F3900I | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV50852511; called by muse, mutect2, varscan2
- NEFH | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs201798049, COSV60215803; called by muse, mutect2, varscan2
- NFRKB | c.3175C>T p.R1059C (on ENST00000446488 / NM_001143835.2; = p.R1084C on NM_006165.3) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs748097962, COSV58756887; called by muse, mutect2, varscan2
- NLGN1 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs770800576, COSV64326205; called by muse, mutect2, varscan2
- NME7 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV63164775, COSV63165617; called by muse, mutect2, varscan2
- NPAT | c.159C>T p.S53= | Splice Region (SNP) | VAF 3/15 reads (20%) | catalogued as rs779697396, COSV53716740; called by muse, mutect2
- NTRK2 | c.1636G>A p.E546K (on ENST00000323115 / NM_001369534.1; = p.E562K on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52855144, COSV52857259; called by muse, mutect2, varscan2
- OBSCN | c.9440G>A p.G3147D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV52751460; called by muse, mutect2, varscan2
- OR12D2 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65830581; called by muse, mutect2, varscan2
- OR13C8 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV58610715; called by muse, mutect2, varscan2
- OR1K1 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV52956280; called by mutect2, varscan2
- OR5P3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs117218570, COSV60429066, COSV60429677; called by muse, mutect2, varscan2
- OR8U1 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs764656297, COSV56414529; called by muse, mutect2, varscan2
- OR9G1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs1374060879, COSV56449240; called by muse, mutect2, varscan2
- OSBP2 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV100213970; called by muse, mutect2, varscan2
- OSBP2 | c.1541C>G p.P514R | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100213971; called by muse, mutect2, varscan2
- OTOP3 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1314024631, COSV60912577; called by muse, mutect2, varscan2
- PCDH17 | c.2974C>T p.P992S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.304); catalogued as COSV64972589; called by muse, mutect2, varscan2
- PCDHA6 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV65350364; called by muse, mutect2, varscan2
- PCDHB3 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV50565665; called by muse, mutect2, varscan2
- PCDHB8 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs782812897, COSV50756691; called by muse, mutect2, varscan2
- PCDHGA2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.072); catalogued as rs534089903, COSV53914168; called by muse, mutect2, varscan2
- PCDHGB1 | c.498A>C p.L166F | Missense Mutation (SNP) | VAF 88/379 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV53914181; called by muse, mutect2, varscan2
- PGK2 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59163159; called by muse, mutect2, varscan2
- PIGR | c.1859G>A p.G620E | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs868338211, COSV62903464; called by muse, mutect2, varscan2
- PKHD1L1 | c.3544G>A p.E1182K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV65739341; called by muse, mutect2, varscan2
- PKP4 | c.2435C>G p.S812W | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV61578154, COSV61579299; called by muse, mutect2, varscan2
- PLCB4 | c.3494C>T p.A1165V (on ENST00000278655 / NM_182797.3; = p.S1177= on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.173); catalogued as rs755565691, COSV53796112; called by muse, mutect2, varscan2
- PLK4 | c.1784T>C p.V595A | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV54636692; called by muse, mutect2, varscan2
- PPFIA2 | c.2864G>A p.R955Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1348041637, COSV61024040; called by muse, mutect2, varscan2
- PRB1 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 147/967 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs1167945774, COSV53702862; called by muse, mutect2, varscan2
- PRDM1 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1445424097, COSV64844725; called by muse, mutect2, varscan2
- PRKDC | c.3739C>T p.P1247S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.728); catalogued as rs1251264942, COSV58046565; called by muse, mutect2
- PTPRG | c.3160G>A p.G1054S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99877515; called by muse, mutect2, varscan2
- PTPRG | c.3161G>A p.G1054D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99877517; called by muse, mutect2, varscan2
- RABGAP1L | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52282249; called by muse, mutect2, varscan2
- RAI1 | c.4519G>T p.A1507S | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV55390458; called by muse, mutect2
- RANBP9 | c.1166T>G p.F389C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50580455; called by muse, mutect2, varscan2
- RET | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); catalogued as rs1276303673, COSV60689044; called by muse, mutect2, varscan2
- RHAG | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486668378, COSV57703450; called by muse, mutect2, varscan2
- RHBDF1 | c.1249G>C p.V417L | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs745494754, COSV51953947; called by muse, mutect2, varscan2
- RNASEH2B | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV60746020; called by muse, mutect2, varscan2
- ROPN1L | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as COSV56873224, COSV56874856; called by muse, mutect2, varscan2
- RORB | c.1144G>A p.D382N (on ENST00000396204 / NM_001365023.1; = p.D371N on NM_006914.4) | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as rs964240475, COSV65333841; called by muse, mutect2
- RPS6KA6 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53117377; called by muse, mutect2, varscan2
- RSAD1 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV51955070; called by muse, mutect2, varscan2
- SAA2 | c.308G>A p.W103* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as COSV99879476; called by muse, mutect2, varscan2
- SAP30 | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.303); catalogued as COSV56634618; called by muse, mutect2, varscan2
- SATB1 | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV58668060; called by muse, varscan2
- SAXO1 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs755681221, COSV65868874; called by muse, mutect2, varscan2
- SCLT1 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs553825676, COSV55402841; called by muse, mutect2, varscan2
- SCN11A | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs374632143, COSV56567263, COSV56569343; called by muse, mutect2, varscan2
- SCN4A | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1227159244, COSV71125975; called by muse, mutect2, varscan2
- SCN5A | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.877); catalogued as rs199473094, CM097630, COSV61118761; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- SCNN1A | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57434645; called by muse, mutect2, varscan2
- SEC16B | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs769306136, COSV57624208; called by muse, mutect2, varscan2
- SELL | c.959G>A p.G320E (on ENST00000650983; = p.G307E on NM_000655.5) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV52550049, COSV52550522; called by muse, mutect2
- SEMG2 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65647299; called by muse, mutect2, varscan2
- SERPINB4 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as COSV61984025; called by muse, mutect2, varscan2
- SEZ6L | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as rs1422059321, COSV99963205; called by muse, mutect2, varscan2
- SLC12A7 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs765864906, COSV53755251; called by muse, mutect2, varscan2
- SLC17A1 | c.131T>C p.M44T | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55077631; called by muse, mutect2, varscan2
- SLC26A8 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs752023890, COSV62884793; called by muse, mutect2, varscan2
- SLC9A9 | c.1380G>A p.M460I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as rs761372851, COSV57221242; called by muse, mutect2, varscan2
- SLC9C2 | c.2882C>T p.T961I | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1273074170, COSV62944486; called by muse, mutect2, varscan2
- SLFN11 | c.229T>A p.L77I | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.606); catalogued as COSV57697959; called by muse, mutect2, varscan2
- SLITRK1 | c.1223A>G p.N408S | Missense Mutation (SNP) | VAF 119/326 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.725); catalogued as rs755712979, COSV65674673; called by muse, mutect2, varscan2
- SPEF2 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV61545565; called by muse, mutect2, varscan2
- SPOCK3 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62719940; called by muse, mutect2, varscan2
- SPTBN4 | c.1510C>T p.R504W | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs761610779, COSV58945239, COSV58953378; called by muse, mutect2, varscan2
- STAB1 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV58733358; called by muse, mutect2, varscan2
- STARD13 | c.1436A>T p.K479I (on ENST00000336934 / NM_001243476.3; = p.K361I on NM_052851.3) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV55228255; called by muse, mutect2, varscan2
- STRC | c.4616G>A p.G1539E | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs868541082, COSV55851988; called by muse, mutect2, varscan2
- SYNE1 | c.529C>T p.Q177* (on ENST00000367255 / NM_182961.4; = p.Q184* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 29/130 reads (22%) | catalogued as COSV54929870; called by muse, mutect2, varscan2
- SYNE2 | c.11765C>T p.S3922L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV59942744; called by muse, mutect2, varscan2
- SYT9 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV59615603; called by muse, mutect2, varscan2
- TACC2 | c.6005G>A p.G2002D (on ENST00000334433; = p.G80D on NM_006997.4) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1479278284, COSV53277787; called by muse, mutect2, varscan2
- TAS2R9 | c.916A>G p.R306G | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV53688190; called by muse, mutect2, varscan2
- TBC1D4 | c.3809C>T p.P1270L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749850246, COSV66488125; called by muse, mutect2, varscan2
- TCHH | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 98/287 reads (34%) | catalogued as COSV64273573; called by muse, mutect2, varscan2
- TEP1 | c.5965G>A p.D1989N | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52989464; called by muse, mutect2, varscan2
- TEX55 | c.1432T>C p.Y478H | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.736); catalogued as COSV55210558; called by muse, mutect2, varscan2
- THSD7B | c.4628A>T p.K1543I (on ENST00000272643; = p.K1541I on NM_001316349.2) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV55663920; called by muse, mutect2, varscan2
- TMEM130 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1264295165, COSV100228504, COSV59558222; called by muse, mutect2, varscan2
- TRPM8 | c.2900C>T p.T967I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100224443, COSV61221113; called by muse, mutect2, varscan2
- TTLL10 | c.421C>T p.L141F (on ENST00000379289 / NM_001130045.2; = p.L68F on NM_153254.3) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); catalogued as COSV64959644; called by muse, mutect2, varscan2
- TTN | c.16561G>A p.D5521N (on ENST00000591111; = p.D4594N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/193 reads (30%) | PolyPhen probably damaging (0.998); catalogued as COSV59935461; called by muse, mutect2, varscan2
- TUBD1 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.848); catalogued as rs983898580, COSV57872183; called by muse, mutect2, varscan2
- UBE2Q2 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51192166; called by muse, mutect2, varscan2
- UGT2A2 | c.267G>C p.K89N | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54139287, COSV99684252; called by muse, mutect2, varscan2
- UGT2B15 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV57732977; called by muse, mutect2, varscan2
- USH1C | c.1080G>A p.M360I | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV50014609; called by muse, mutect2, varscan2
- VPS13B | c.9032T>C p.V3011A | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV62136025, COSV62148243; called by muse, mutect2, varscan2
- VPS9D1 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV66994055; called by muse, mutect2
- VWF | c.7897G>A p.E2633K | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.028); catalogued as COSV54613960; called by muse, mutect2, varscan2
- WFDC2 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.056); catalogued as COSV54151079; called by muse, mutect2, varscan2
- XIRP2 | c.6829G>A p.D2277N (on ENST00000628543; = p.D2452N on NM_152381.6) | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as COSV54686355, COSV54687430; called by muse, mutect2, varscan2
- YLPM1 | c.5242C>T p.R1748* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV53107765; called by muse, mutect2, varscan2
- ZBTB41 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.655); catalogued as rs1388932121, COSV66358832; called by muse, mutect2, varscan2
- ZC3H10 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV57768405; called by muse, mutect2, varscan2
- ZC3H12B | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV59046790; called by muse, mutect2, varscan2
- ZCCHC13 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV59866035; called by muse, mutect2, varscan2
- ZNF248 | c.1197G>T p.Q399H | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV61997329; called by muse, mutect2, varscan2
- ZNF280A | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57479804; called by muse, mutect2, varscan2
- ZNF479 | c.1034G>A p.R345K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as rs1335608758, COSV58636692, COSV58636789, COSV58637452; called by muse, mutect2, varscan2
- ZNF585B | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as rs368332359; called by muse, mutect2, varscan2
- ZNF658 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs146060713; called by muse, mutect2, varscan2
- ZUP1 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV63944135; called by muse, mutect2, varscan2
- ZZEF1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); catalogued as COSV56800367; called by muse, mutect2, varscan2
- AP1B1 | c.701_716+7del p.X234_splice | Splice Site (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel
- GFM2 | c.1727-4_1770del p.X576_splice | Splice Site (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- HHIP | c.1392_1423del p.I465Kfs*2 | Frame Shift Del (DEL) | VAF 9/95 reads (9%) | called by mutect2, pindel
- RAB6D | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRBV4-2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- ACTB | c.63C>T p.F21= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs370972197, COSV59319554, COSV59319716; ClinVar: likely benign; called by muse, mutect2, varscan2
- AFAP1 | c.972C>T p.I324= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV61794073; called by muse, mutect2, varscan2
- AHNAK | c.14379C>T p.F4793= | Silent (SNP) | VAF 104/319 reads (33%) | catalogued as rs1272978572, COSV57206510, COSV57226377; called by muse, mutect2, varscan2
- AKAP3 | c.1797G>A p.R599= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as COSV57414902; called by muse, mutect2, varscan2
- ALLC | c.315C>T p.I105= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV52993466; called by muse, mutect2, varscan2
- AOX1 | c.144C>T p.G48= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV65980621; called by muse, mutect2, varscan2
- ARHGAP36 | c.153G>A p.S51= | Silent (SNP) | VAF 58/222 reads (26%) | catalogued as COSV52264880; called by muse, mutect2, varscan2
- C2orf16 | c.4275G>A p.E1425= | Silent (SNP) | VAF 46/93 reads (49%) | catalogued as COSV62674284; called by muse, mutect2, varscan2
- C5 | c.42G>A p.G14= | Silent (SNP) | VAF 10/141 reads (7%) | catalogued as COSV56324850; called by muse, mutect2
- C7orf57 | c.522C>T p.A174= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV62362146; called by muse, mutect2, varscan2
- CABLES1 | c.1815C>T p.F605= (on ENST00000256925 / NM_001100619.2; = p.F340= on NM_138375.2) | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV56931652; called by muse, mutect2, varscan2
- CCDC93 | c.963C>T p.S321= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100099683; called by muse, mutect2, varscan2
- CDH17 | c.642G>A p.K214= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV50326323; called by muse, mutect2, varscan2
- CDH22 | c.1461C>T p.I487= | Silent (SNP) | VAF 76/230 reads (33%) | catalogued as COSV64836813; called by muse, mutect2, varscan2
- CDHR4 | c.159G>A p.L53= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV58525889; called by muse, mutect2, varscan2
- CEBPE | c.375G>A p.R125= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV52829266; called by muse, mutect2, varscan2
- CELSR1 | c.4014C>T p.F1338= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99420642; called by muse, mutect2, varscan2
- CFTR | c.1470C>T p.F490= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as CD962511, COSV50043400, COSV99136895; called by muse, mutect2, varscan2
- CILP | c.2271G>A p.R757= | Silent (SNP) | VAF 65/205 reads (32%) | catalogued as COSV56022619; called by muse, mutect2, varscan2
- CLDND1 | c.162C>T p.F54= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV57858356, COSV57858532; called by muse, mutect2, varscan2
- CNGB1 | c.3027C>T p.V1009= | Silent (SNP) | VAF 64/234 reads (27%) | catalogued as COSV51898655; called by muse, mutect2, varscan2
- COL12A1 | c.4714C>T p.L1572= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV59391596; called by muse, mutect2, varscan2
- COL19A1 | c.2868G>A p.G956= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs1427074024, COSV59567999; called by muse, mutect2
- CXCR1 | c.522C>T p.F174= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV55281324; called by mutect2, varscan2
- DGCR2 | c.990C>T p.F330= | Silent (SNP) | VAF 100/296 reads (34%) | catalogued as rs1371160566, COSV54217043; called by muse, mutect2, varscan2
- DHTKD1 | c.2415C>T p.L805= | Silent (SNP) | VAF 84/262 reads (32%) | catalogued as rs1460366028, COSV53801438; called by muse, mutect2, varscan2
- DNAH17 | c.4405C>T p.L1469= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV67750936; called by muse, mutect2, varscan2
- DNAH5 | c.5691G>A p.R1897= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV54210610; called by muse, mutect2, varscan2
- DPP10 | c.1611C>T p.I537= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV59671811; called by muse, mutect2
- ELN | c.567C>T p.I189= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV52708113; called by muse, mutect2, varscan2
- EPG5 | c.7398C>T p.I2466= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV56346213; called by muse, mutect2, varscan2
- ETV6 | c.613C>T p.L205= | Silent (SNP) | VAF 94/306 reads (31%) | catalogued as COSV67148497, COSV67148622; called by muse, mutect2, varscan2
- FAM155B | c.582C>T p.F194= | Silent (SNP) | VAF 31/101 reads (31%) | catalogued as COSV52935516; called by muse, mutect2, varscan2
- FAR1 | c.1024C>T p.L342= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV61384238; called by muse, mutect2, varscan2
- FERMT1 | c.669A>G p.Q223= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV54091625; called by muse, mutect2, varscan2
- FLVCR2 | c.69G>A p.A23= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV99471678; called by muse, mutect2, varscan2
- GAK | c.861C>T p.V287= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs1461171155, COSV58503409; called by muse, mutect2, varscan2
- GINS4 | c.618C>T p.I206= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as rs772826423, COSV52531039; called by muse, mutect2, varscan2
- GRB10 | c.417C>T p.P139= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV60007692; called by muse, mutect2, varscan2
- GRB7 | c.537C>T p.F179= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs149753893; called by muse, mutect2, varscan2
- IFNA21 | c.417C>T p.S139= | Silent (SNP) | VAF 97/205 reads (47%) | catalogued as COSV66518229; called by muse, mutect2, varscan2
- IGHG3 | c.45C>T p.S15= | Silent (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- IGHV4-39 | c.270C>T p.S90= | Silent (SNP) | VAF 56/217 reads (26%) | catalogued as rs780743205; called by muse, varscan2
- IGKV6D-21 | c.270C>T p.F90= | Silent (SNP) | VAF 45/153 reads (29%) | called by muse, mutect2, varscan2
- IHO1 | c.840C>T p.S280= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs749595438, COSV99606724; called by muse, mutect2, varscan2
- IPO8 | c.2922C>T p.A974= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV56240177; called by muse, mutect2
- ITGB3 | c.2265A>G p.K755= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV71383577; called by muse, mutect2, varscan2
- ITPKB | c.540C>T p.F180= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV99685419; called by muse, mutect2, varscan2
- KANK2 | c.2280C>T p.A760= (on ENST00000586659 / NM_001379562.1; = p.A768= on NM_015493.7 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV100763281; called by muse, mutect2, varscan2
- KCND3 | c.138G>A p.V46= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as COSV56176931; called by muse, mutect2, varscan2
- KCNJ5 | c.507G>A p.L169= | Silent (SNP) | VAF 54/175 reads (31%) | catalogued as COSV57964101; called by muse, mutect2, varscan2
- KIF4B | c.1854G>A p.E618= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as COSV70528404; called by muse, mutect2, varscan2
- KL | c.2172G>A p.G724= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs749586705, COSV66308134; called by muse, mutect2, varscan2
- KLHL22 | c.349C>T p.L117= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV61020116; called by muse, mutect2, varscan2
- LCA5 | c.1974C>T p.F658= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs201047397, COSV63970707; called by muse, mutect2, varscan2
- LRRIQ4 | c.618G>A p.E206= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as COSV61618831; called by muse, mutect2, varscan2
- LUM | c.615C>T p.V205= | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as rs760543022, COSV57127681; called by muse, mutect2, varscan2
- MDN1 | c.5253G>A p.L1751= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs371677004; called by muse, mutect2, varscan2
- ME2 | c.1677G>A p.R559= | Silent (SNP) | VAF 40/128 reads (31%) | catalogued as COSV58422549; called by muse, mutect2, varscan2
- MEGF11 | c.1809C>T p.P603= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs760705880, COSV56546584; called by muse, mutect2, varscan2
- MEP1B | c.1182G>A p.V394= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV52496227; called by muse, mutect2, varscan2
- MERTK | c.1380G>A p.R460= | Silent (SNP) | VAF 62/212 reads (29%) | catalogued as COSV54925776; called by muse, mutect2
- MRGPRX1 | c.831C>T p.S277= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as rs1351183065, COSV100245815, COSV57106293; called by muse, mutect2, varscan2
- MTRR | c.2110C>T p.L704= (on ENST00000264668; = p.L677= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as COSV52942260; called by muse, mutect2, varscan2
- MVK | c.150C>T p.D50= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV57169657; called by muse, mutect2, varscan2
- MYB | c.1128C>T p.I376= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs780660118, COSV57196753; called by muse, mutect2, varscan2
- MYO15A | c.324G>A p.V108= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV52753415; called by muse, mutect2, varscan2
- MYO18B | c.3213C>T p.S1071= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as rs748623336, COSV59128425; called by muse, mutect2, varscan2
- NELL1 | c.372G>A p.E124= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV54246285; called by muse, mutect2, varscan2
- NFATC3 | c.654C>A p.G218= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as COSV60471761; called by muse, mutect2, varscan2
- NTNG2 | c.735G>A p.E245= | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as COSV62365218; called by muse, mutect2
- OBP2A | c.240G>A p.L80= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs1420553370, COSV59791194; called by muse, mutect2, varscan2
- OBP2B | c.240G>A p.L80= | Silent (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- OCM | c.201C>T p.F67= | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- OR10A3 | c.351G>A p.A117= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as rs755678038, COSV62459285; called by muse, mutect2, varscan2
- OR10G2 | c.79C>T p.L27= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as COSV73390328; called by muse, mutect2, varscan2
- OR12D2 | c.474C>T p.S158= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as rs756977247, COSV65830583; called by muse, mutect2, varscan2
- OR1F1 | c.762C>T p.T254= | Silent (SNP) | VAF 46/186 reads (25%) | catalogued as COSV58960578; called by muse, mutect2, varscan2
- OR2AT4 | c.831C>T p.I277= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as rs1244963085, COSV59406543; called by muse, mutect2, varscan2
- OR2M3 | c.855G>A p.L285= | Silent (SNP) | VAF 57/146 reads (39%) | catalogued as COSV71758929; called by muse, mutect2, varscan2
- OR2T3 | c.870G>A p.L290= | Silent (SNP) | VAF 33/268 reads (12%) | catalogued as COSV62081992; called by mutect2, varscan2
- OR2T34 | c.870G>A p.L290= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100170606; called by muse, mutect2, varscan2
- OR4C15 | c.150T>C p.F50= | Silent (SNP) | VAF 41/146 reads (28%) | catalogued as COSV58950991, COSV58951616; called by muse, mutect2, varscan2
- OR56A3 | c.294C>T p.F98= | Silent (SNP) | VAF 69/229 reads (30%) | catalogued as rs772380308, COSV61568646; called by muse, mutect2, varscan2
- OR5M10 | c.36C>T p.F12= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV73242269; called by muse, mutect2, varscan2
- OTOP1 | c.1287C>T p.S429= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs763547873, COSV56391573; called by muse, mutect2, varscan2
- PACRG | c.282C>T p.I94= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as rs76289683, COSV61299198; called by muse, mutect2, varscan2
- PAPLN | c.831C>T p.P277= (on ENST00000554301; = p.P250= on NM_173462.4) | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV53714725; called by muse, mutect2, varscan2
- PCDHA10 | c.348C>T p.F116= | Silent (SNP) | VAF 86/234 reads (37%) | catalogued as COSV56484415; called by muse, mutect2, varscan2
- PCDHA5 | c.1065C>T p.F355= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs782779117, COSV65350160; called by muse, mutect2, varscan2
- PCDHA9 | c.1425C>T p.F475= | Silent (SNP) | VAF 65/169 reads (38%) | catalogued as COSV65324237, COSV65328881; called by muse, mutect2, varscan2
- PCDHGA4 | c.1458T>A p.A486= | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as COSV53914196, COSV53924167; called by muse, mutect2, varscan2
- PCSK7 | c.247C>T p.L83= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV56117947; called by muse, mutect2, varscan2
- PEPD | c.912C>T p.A304= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs199621901; called by muse, mutect2, varscan2
- PIWIL1 | c.2337C>T p.I779= | Silent (SNP) | VAF 40/145 reads (28%) | catalogued as rs1181198037, COSV55344928; called by muse, mutect2, varscan2
- PKDREJ | c.6213C>T p.F2071= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV53546171, COSV53547286, COSV99479204; called by muse, mutect2, varscan2
- PLXNA4 | c.1029G>A p.Q343= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV100326133, COSV58111478; called by muse, mutect2, varscan2
- PRKDC | c.6474C>T p.R2158= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV58046555; called by muse, mutect2, varscan2
- PSD2 | c.528C>T p.F176= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs746530359, COSV51197496; called by muse, mutect2, varscan2
- PTK7 | c.237C>T p.F79= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs370691630; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1668C>T p.S556= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV54758803; called by muse, mutect2, varscan2
- RAI1 | c.4521C>T p.A1507= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs1453032967, COSV55390473; called by muse, mutect2
- RAP1GAP2 | c.1698C>T p.L566= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV54573544; called by muse, mutect2, varscan2
- RTN2 | c.1128C>T p.I376= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1288742843, COSV55593042; called by muse, mutect2, varscan2
- SATB1 | c.999G>A p.V333= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV58668056; called by muse, varscan2
- SEZ6L | c.705G>A p.E235= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV99961073; called by muse, mutect2, varscan2
- SH2B1 | c.1809C>T p.H603= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as COSV59461308; called by muse, mutect2, varscan2
- SHISA2 | c.378C>T p.V126= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs778644433, COSV60110269; called by muse, mutect2, varscan2
- SLC22A10 | c.1057C>T p.L353= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs1430575918, COSV60420475; called by muse, mutect2
- SLC2A9 | c.1164T>C p.F388= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV53317790; called by muse, mutect2, varscan2
- SLC34A2 | c.1776C>T p.F592= | Silent (SNP) | VAF 59/180 reads (33%) | catalogued as COSV65940935; called by muse, varscan2
- SLC39A5 | c.711G>A p.L237= | Silent (SNP) | VAF 78/215 reads (36%) | catalogued as COSV57190959; called by muse, mutect2, varscan2
- SLC41A2 | c.1524C>T p.G508= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs181418153; called by muse, mutect2, varscan2
- SLC6A7 | c.285C>T p.L95= | Silent (SNP) | VAF 69/251 reads (27%) | catalogued as rs780659646, COSV100046465, COSV57937234; called by muse, mutect2, varscan2
- SLCO1A2 | c.1719C>T p.S573= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as rs1302085510, COSV56598673; called by muse, mutect2, varscan2
- SLFN5 | c.174C>T p.I58= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as COSV55480101; called by muse, mutect2, varscan2
- SMO | c.1524G>A p.E508= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs267601281, COSV50825057, COSV99977036; called by muse, mutect2, varscan2
- STK31 | c.702G>A p.R234= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV63454620; called by muse, mutect2, varscan2
- STRA6 | c.1035C>T p.S345= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs377002129, COSV100121357; called by muse, mutect2, varscan2
- TENM3 | c.3768C>T p.V1256= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as rs375491156; ClinVar: likely benign; called by muse, mutect2, varscan2
- TIMP4 | c.414G>A p.E138= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs1237440174, COSV55138781, COSV55138856; called by muse, mutect2, varscan2
- TMEM184A | c.183C>T p.I61= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99869099; called by muse, mutect2, varscan2
- TPCN1 | c.1338C>T p.F446= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV59233328; called by muse, mutect2, varscan2
- TRPC7 | c.702C>T p.S234= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV61454429; called by muse, mutect2, varscan2
- TSC1 | c.516G>A p.V172= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as rs1419763219, COSV53764816; called by muse, mutect2, varscan2
- TTN | c.37713A>G p.K12571= (on ENST00000591111; = p.K5147= on NM_003319.4) | Silent (SNP) | VAF 63/192 reads (33%) | catalogued as CD1514710, COSV59935436; called by muse, mutect2, varscan2
- WBP11 | c.540T>A p.V180= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV53762139; called by muse, mutect2, varscan2
- WNK4 | c.2085C>A p.T695= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as COSV55902299; called by muse, mutect2, varscan2
- XCR1 | c.300C>T p.F100= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV58569236; called by muse, mutect2, varscan2
- ZBTB46 | c.831G>A p.E277= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as rs1216510767, COSV99829811; called by muse, mutect2, varscan2
- ZNF426 | c.1173T>C p.P391= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs373322693; called by muse, mutect2, varscan2
- ZNF624 | c.606C>T p.G202= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV60939484; called by muse, mutect2, varscan2
- ZNF713 | c.945C>T p.S315= (on ENST00000633730 / NM_001366796.2; = p.S328= on NM_182633.3) | Silent (SNP) | VAF 43/127 reads (34%) | catalogued as COSV70056483; called by muse, mutect2, varscan2
- DCX | c.-22-471C>T | Intron (SNP) | VAF 73/238 reads (31%) | catalogued as COSV100576849; called by muse, mutect2, varscan2
- DCX | c.-22-472C>T | Intron (SNP) | VAF 75/236 reads (32%) | catalogued as COSV57568302; called by muse, mutect2, varscan2
- FOLH1B | n.2040G>A | RNA (SNP) | VAF 40/153 reads (26%) | catalogued as rs1460024056; called by muse, mutect2, varscan2
- KIR3DX1 | n.336C>T | RNA (SNP) | VAF 17/35 reads (49%) | catalogued as COSV99683815; called by muse, mutect2, varscan2
- KRTAP12-3 | c.*2C>A | 3'UTR (SNP) | VAF 23/58 reads (40%) | catalogued as COSV100556106; called by muse, mutect2, varscan2
- LEKR1 | c.*612G>A | 3'UTR (SNP) | VAF 14/42 reads (33%) | catalogued as COSV62960983; called by muse, mutect2, varscan2
- LYVE1 | c.-1G>A | 5'UTR (SNP) | VAF 10/34 reads (29%) | catalogued as rs766130151, COSV99810972; called by muse, mutect2
- MARCHF1 | c.-322-85667G>A | Intron (SNP) | VAF 42/172 reads (24%) | catalogued as rs376308693; called by muse, mutect2, varscan2
- MIR325 | n.17C>T | RNA (SNP) | VAF 45/141 reads (32%) | called by muse, mutect2, varscan2
- OGFOD3 | c.824-1993G>A | Intron (SNP) | VAF 32/111 reads (29%) | catalogued as COSV57339650; called by muse, mutect2, varscan2
- PGM1 | c.247-5826T>C | Intron (SNP) | VAF 19/53 reads (36%) | catalogued as rs762587514, COSV64300177; called by muse, mutect2, varscan2
- RPL26P30 | n.837G>A | RNA (SNP) | VAF 75/227 reads (33%) | catalogued as rs748343427; called by muse, mutect2, varscan2
- S1PR3 | c.*2C>T | 3'UTR (SNP) | VAF 11/34 reads (32%) | catalogued as rs778549047, COSV100822644; called by muse, mutect2
